Gene-level copy-number profile of tumor specimen C3N-03614-01 (profiled together with C3N-03614-02) from CPTAC case C3N-03614, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.3 years (27,854 days).
Specimen C3N-03614-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c145c041-977f-4bb3-b52b-0cd5607daaab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03614-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/04fa0104-4836-4f8d-90e9-b82966853ce0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 731; copy number 2: 37,088; copy number 3: 12,146; copy number 4: 7,336; copy number 5: 1,098; copy number 6: 175; copy number 7: 66; copy number 8: 12; copy number 9: 7; copy number 10: 80; copy number 11: 38; copy number 12: 2; copy number 13: 36; copy number 15: 6; copy number 16: 3; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,928,253, 11 genes (within-gene range 0–10): PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr1:143,541,768–143,797,108, 13 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr15:43,826,980–44,778,721, 22 genes: WDR76, Y_RNA, FRMD5, PIN4P1, ACTBP7, GAPDHP55, GOLM2, GAPDHP43, AC090519.1, AC025043.1, CTDSPL2, HNRNPMP1, AC025430.1, EIF3J-DT, EIF3J, AC009996.1, SPG11, PATL2, Y_RNA, B2M, TRIM69, AC122108.2.
- chr16:32,185,624–32,202,822, 4 genes (within-gene range 0–2): AC133485.6, AC133485.5, AC133485.4, ABHD17AP8.
- chr16:32,289,547–32,436,203, 4 genes: AC133548.2, AC133548.1, ACTR3BP3, AC138915.2.
- chr16:32,454,612–32,636,045, 6 genes: AC138915.3, AC138915.1, ABCD1P3, AC137800.1, AC137800.2, AC133569.1.
- chr16:32,845,964–32,848,156, 2 genes: AC142086.2, IGHV2OR16-5.
- chr16:32,882,586–32,888,874, 1 gene (within-gene range 0–3): AC142086.1.
- chr16:32,915,074–33,095,431, 11 genes (within-gene range 0–2): IGHV3OR16-6, AC142086.6, AC142086.3, AC142086.5, IGHV1OR16-2, IGHV3OR16-10, AC142086.4, IGHV1OR16-4, IGHV3OR16-8, AC145350.2, AC145350.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,512 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,203,430–155,062,775, 110 genes, copy number 6 (broad region; genes not listed).
- chr1:159,346,166–159,469,068, 1 gene, copy number 5 (within-gene range 4–5): AL513323.1.
- chr1:159,405,423–161,678,654, 119 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:52,193,170–52,288,020, 10 genes, copy number 10 (within-gene range 3–10): ALDOAP1, ALAS1, AC097637.2, TLR9, AC097637.1, TWF2, AC006252.1, PPM1M, WDR82, MIRLET7G.
- chr3:57,293,083–61,251,459, 52 genes, copy number 10: AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16, FLNB, FLNB-AS1, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1, AC126121.3, AC138057.1, AC126121.2, AC126121.1, Metazoa_SRP, FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr3:62,950,430–65,193,509, 32 genes, copy number 11: LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040.
- chr3:66,378,797–79,958,142, 140 genes, copy number 7–18 (within-gene range 3–18) (broad region; genes not listed).
- chr3:82,806,515–82,808,021, 1 gene, copy number 12: CYP51A1P1.
- chr3:86,816,740–87,276,584, 7 genes, copy number 5–13: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr3:105,366,909–106,326,293, 3 genes, copy number 11–13: ALCAM, CBLB, AC079382.1.
- chr3:106,515,897–106,691,320, 3 genes, copy number 13: Y_RNA, AC080097.1, Y_RNA.
- chr3:106,896,891–106,898,268, 2 genes, copy number 13 (within-gene range 3–13): MTCO3P35, MTATP6P22.
- chr3:106,900,593–106,901,965, 3 genes, copy number 13 (within-gene range 3–13): MTND6P6, MTCO1P35, MTND1P16.
- chr7:5,823,160–7,293,880, 53 genes, copy number 5: ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP, AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1.
- chr7:99,546,300–101,629,296, 125 genes, copy number 5 (broad region; genes not listed).
- chr7:105,876,796–108,639,349, 47 genes, copy number 5: CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1.
- chr7:127,580,628–129,785,185, 84 genes, copy number 5 (broad region; genes not listed).
- chr8:12,393,209–12,400,366, 1 gene, copy number 5: DEFB109A.
- chr8:79,520,145–80,595,703, 32 genes, copy number 5: AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3.
- chr11:9,660,438–10,541,230, 19 genes, copy number 5: AC011979.1, SWAP70, RN7SKP50, LINC02709, SBF2-AS1, SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3, AC100763.1, AC080023.2, AC080023.1, ADM, AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141.
- chr16:32,439,069–32,441,159, 1 gene, copy number 6: PABPC1P13.
- chr16:32,869,985–32,873,128, 1 gene, copy number 15: BCAP31P2.
- chr20:50,888,916–52,699,472, 26 genes, copy number 5: ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1.
- chr20:61,252,261–63,104,386, 66 genes, copy number 5 (broad region; genes not listed).
- chr22:17,036,570–20,704,606, 176 genes, copy number 5 (broad region; genes not listed).
- chr22:21,473,000–25,197,448, 263 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:26,161,834–26,780,893, 25 genes, copy number 5: LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3.
- chr22:27,563,839–30,030,868, 68 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:31,618,491–32,498,829, 42 genes, copy number 5 (within-gene range 4–5): PISD, MIR7109, PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1, SLC5A4-AS1, SLC5A4, CPSF1P1, AL008723.2, AL021937.3, RFPL3, IGLCOR22-2, RFPL3S, AL021937.6, AL021937.5, AL021937.1, IGLVIVOR22-2, AL021937.4, AL021937.2, RTCB, BPIFC, FBXO7.

Autosomal genes at a single copy (total copy number 1): 731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
